Somatic mutation profile of tumor specimen TCGA-AJ-A3NG-01A (aliquot TCGA-AJ-A3NG-01A-11D-A228-09) from TCGA case TCGA-AJ-A3NG, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 83.1 years (30,351 days).
Specimen TCGA-AJ-A3NG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7627aaac-b972-488c-a816-aed8155e9212.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AJ-A3NG-10A (Blood Derived Normal), aliquot TCGA-AJ-A3NG-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe027071-ef87-40fa-8d16-273837633c7f

The open-access MAF lists 86 somatic variants for this specimen: 64 protein-altering or splice-affecting, 22 silent.
By variant classification: Missense Mutation 58, Silent 22, Frame Shift Del 4, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GJB2 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs104894401, CM010311, CM077557, COSV67010639; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 19/24 reads (79%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 39/113 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 54/116 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMARCB1 | c.982C>T p.R328W (on ENST00000263121; = p.R374W on NM_003073.5) | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1568963596, COSV51954374, COSV51955307; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SOX17 | c.1208G>T p.S403I | Missense Mutation (SNP) | VAF 57/112 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52024163; called by muse, mutect2, varscan2
- ACAN | c.5390G>A p.G1797E | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV100719024; called by muse, mutect2, varscan2
- CRB1 | c.3230A>G p.N1077S | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.197); catalogued as COSV100958051; called by muse, mutect2, varscan2
- DLG2 | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.007); catalogued as COSV101073189; called by muse, mutect2
- DNAH5 | c.4960C>T p.R1654W | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs139364454; called by muse, mutect2, varscan2
- DNAH9 | c.2656T>A p.S886T | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV99307556; called by muse, mutect2, varscan2
- DNMBP | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs138795130, COSV60634393; called by muse, mutect2, varscan2
- ESAM | c.562G>T p.D188Y | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as rs771286783, COSV54035389, COSV99631586; called by muse, mutect2, varscan2
- FBN2 | c.4792G>A p.G1598R | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1292570631, COSV99330025; called by muse, mutect2, varscan2
- FGF18 | c.284G>A p.S95N | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.107); catalogued as COSV99209715; called by muse, mutect2, varscan2
- FLOT2 | c.307G>A p.V103I | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs777162321, COSV67529033; called by muse, mutect2, varscan2
- GLIS1 | c.1196T>G p.L399R | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.795); catalogued as COSV100390651; called by muse, mutect2, varscan2
- HAAO | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs1053125533, COSV99685512; called by muse, mutect2, varscan2
- HAUS6 | c.1840G>T p.D614Y | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100997891; called by muse, mutect2, varscan2
- KAZN | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1159330216, COSV63210090; called by muse, mutect2, varscan2
- KIAA1614 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100851342; called by muse, mutect2, varscan2
- KMT2D | c.15224G>T p.G5075V | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56445969, COSV99040264; called by muse, mutect2, varscan2
- LHX4 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.278); catalogued as rs752455651, CM1210489, COSV55374671; called by muse, mutect2, varscan2
- MAN2C1 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as rs1317761186, COSV99145738; called by muse, mutect2, varscan2
- MUC16 | c.36397C>A p.P12133T | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.251); catalogued as COSV101201084; called by muse, mutect2
- NAV2 | c.2788C>T p.R930W (on ENST00000396087 / NM_001244963.2; = p.R907W on NM_145117.5) | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs775581508, COSV62335933; called by muse, mutect2, varscan2
- NAV2 | c.4940G>A p.R1647H | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs771139211, COSV100217527; called by muse, mutect2, varscan2
- NLRP7 | c.2810G>A p.R937Q (on ENST00000340844 / NM_206828.3; = p.R909H on NM_139176.3) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.523); catalogued as rs759185995, COSV100053213; called by muse, mutect2, varscan2
- NPHP3 | c.3184A>C p.K1062Q | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV100447272; called by muse, mutect2, varscan2
- OPRPN | c.94G>T p.G32C | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.988); catalogued as COSV101271100, COSV68192569; called by muse, mutect2
- OR2Z1 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV100136516; called by muse, mutect2, varscan2
- OR4C12 | c.241G>T p.V81L | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV100078644; called by muse, mutect2, varscan2
- PCDHGA7 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.248); catalogued as COSV99544890; called by muse, varscan2
- PGBD2 | c.1581C>A p.S527R | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.346); catalogued as COSV100252195; called by muse, mutect2, varscan2
- POLH | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758423288, CM020292, COSV64779954; called by muse, mutect2, varscan2
- PPP1R12C | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99670349; called by muse, mutect2, varscan2
- PRAMEF20 | c.1154G>A p.R385H | Missense Mutation (SNP) | VAF 26/376 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.703); catalogued as rs965592462; called by muse, mutect2
- REXO1 | c.3649G>A p.A1217T | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as rs1276949112, COSV99402512; called by muse, mutect2, varscan2
- RNASE3 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as rs1351490375, COSV58959508, COSV58960113; called by muse, mutect2, varscan2
- SETBP1 | c.4173C>T p.V1391= | Splice Region (SNP) | VAF 40/107 reads (37%) | catalogued as COSV99954517; called by muse, mutect2, varscan2
- SH2D3C | c.2096G>A p.R699Q (on ENST00000314830 / NM_170600.3; = p.R542Q on NM_005489.4) | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773273538, COSV100137321; called by muse, varscan2
- SLC25A24 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs374953372; called by muse, mutect2, varscan2
- SLC25A48 | c.536G>A p.R179Q (on ENST00000650267; = p.R125Q on NM_001349335.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs371126144, COSV50852365, COSV99192152; called by muse, mutect2, varscan2
- SLC35A2 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1171450247, COSV99900471; called by muse, mutect2, varscan2
- SPTA1 | c.3136C>T p.R1046* | Nonsense Mutation (SNP) | VAF 26/91 reads (29%) | catalogued as COSV63751069; called by muse, mutect2, varscan2
- TAF1L | c.3044G>A p.R1015H | Missense Mutation (SNP) | VAF 80/176 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774366817, COSV54261717; called by muse, mutect2, varscan2
- TBXA2R | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT tolerated (0.64); PolyPhen benign (0.039); catalogued as COSV64343990; called by muse, mutect2, varscan2
- TDRD3 | c.20C>T p.T7I | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99541038; called by muse, mutect2, varscan2
- TRIM23 | c.725A>G p.E242G | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV99140175; called by muse, mutect2, varscan2
- TRIM62 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1473005265, COSV99357938; called by muse, mutect2, varscan2
- UBE2O | c.1705C>T p.R569C | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV60060332; called by muse, mutect2, varscan2
- VWA2 | c.1735G>A p.V579M | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.776); catalogued as rs1040404585, COSV100073915; called by muse, mutect2, varscan2
- VWC2L | c.5C>A p.A2D | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.266); catalogued as COSV100436231; called by muse, mutect2, varscan2
- WDFY3 | c.4607A>G p.N1536S | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs759562790, COSV99885133; called by muse, mutect2, varscan2
- WDR83 | c.425G>C p.R142T | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV52952872, COSV99269742; called by muse, mutect2, varscan2
- WWP1 | c.1223C>T p.T408M | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1371065516, COSV99616990; called by muse, mutect2, varscan2
- XRN2 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV101018552, COSV65868213; called by muse, mutect2, varscan2
- ZNF548 | c.191T>C p.F64S | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV100278266; called by muse, mutect2
- ZNF875 | c.569A>G p.N190S | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100183518; called by muse, mutect2, varscan2
- ATP10D | c.2006del p.A669Vfs*37 | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | called by mutect2, pindel, varscan2
- ATP8B3 | c.2935C>A p.Q979K | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2
- CDH10 | c.306del p.F102Lfs*36 | Frame Shift Del (DEL) | VAF 27/74 reads (36%) | called by mutect2, pindel, varscan2
- HNF1B | c.1171_1186del p.P391Sfs*7 | Frame Shift Del (DEL) | VAF 35/104 reads (34%) | called by mutect2, pindel, varscan2
- PGR | c.2685del p.F895Lfs*7 | Frame Shift Del (DEL) | VAF 35/58 reads (60%) | called by mutect2, pindel, varscan2
- ACE | c.711G>A p.E237= | Silent (SNP) | VAF 39/107 reads (36%) | catalogued as COSV99327586; called by muse, mutect2, varscan2
- CCDC88C | c.2322C>T p.S774= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV101106064; called by muse, mutect2, varscan2
- CSMD3 | c.7491C>T p.T2497= (on ENST00000297405 / NM_001363185.1; = p.T2393= on NM_052900.3) | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as rs772127285, COSV99844371; called by muse, mutect2, varscan2
- DOK2 | c.516C>T p.L172= | Silent (SNP) | VAF 33/203 reads (16%) | catalogued as rs756338298, COSV52388952, COSV99374905; called by muse, mutect2, varscan2
- FAM163A | c.327G>A p.T109= | Silent (SNP) | VAF 62/114 reads (54%) | catalogued as rs780622657, COSV59203184; called by muse, mutect2, varscan2
- FKBP11 | c.510C>T p.G170= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as rs755875914, COSV99872865; called by muse, mutect2, varscan2
- HBA1 | c.48T>C p.G16= | Silent (SNP) | VAF 17/103 reads (17%) | catalogued as COSV99285426; called by muse, mutect2
- ILVBL | c.1767C>T p.L589= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV54621281, COSV99655084; called by muse, mutect2, varscan2
- INTS1 | c.2874A>G p.L958= | Silent (SNP) | VAF 10/268 reads (4%) | catalogued as rs1354223546, COSV101248253; called by muse, mutect2
- MGAT5B | c.1557G>A p.E519= (on ENST00000569840 / NM_001199172.2; = p.E517= on NM_144677.3) | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as rs775897025, COSV100048770; called by muse, mutect2, varscan2
- OAZ1 | c.621G>A p.K207= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as COSV100457425; called by muse, mutect2, varscan2
- OR52E4 | c.288T>C p.F96= | Silent (SNP) | VAF 42/125 reads (34%) | catalogued as COSV100389338; called by muse, mutect2, varscan2
- OR8I2 | c.267G>A p.R89= | Silent (SNP) | VAF 26/80 reads (33%) | catalogued as rs761448342, COSV100136229; called by muse, mutect2, varscan2
- PTPN5 | c.1461C>A p.P487= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV100080244; called by muse, mutect2, varscan2
- RABGEF1 | c.966G>A p.P322= (on ENST00000439720 / NM_001287061.2; = p.P309= on NM_014504.3 and 29 other RefSeq transcripts) | Silent (SNP) | VAF 57/118 reads (48%) | catalogued as rs771574875, COSV99535037; called by muse, mutect2, varscan2
- SHMT2 | c.43A>C p.R15= | Silent (SNP) | VAF 64/186 reads (34%) | catalogued as COSV100197346; called by muse, mutect2, varscan2
- SNED1 | c.1881C>T p.P627= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as COSV60024077; called by muse, mutect2, varscan2
- STEAP4 | c.918C>G p.L306= | Silent (SNP) | VAF 32/98 reads (33%) | catalogued as COSV100112620, COSV100112688; called by muse, mutect2, varscan2
- TNFRSF10A | c.1344G>A p.L448= | Silent (SNP) | VAF 30/128 reads (23%) | catalogued as COSV99646337; called by muse, mutect2, varscan2
- ZC3H7B | c.2832C>T p.D944= | Silent (SNP) | VAF 76/184 reads (41%) | catalogued as rs774972968, COSV100687661; called by muse, mutect2, varscan2
- ZFHX4 | c.9297C>T p.P3099= | Silent (SNP) | VAF 41/79 reads (52%) | catalogued as COSV50630947, COSV50782853, COSV99266468; called by muse, mutect2, varscan2
- ZSWIM8 | c.1098C>T p.A366= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as COSV101290105; called by muse, mutect2, varscan2
